Somatic mutation profile of tumor specimen TCGA-44-2666-01A (aliquot TCGA-44-2666-01A-41D-A27T-08) from TCGA case TCGA-44-2666, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 43.7 years (15,970 days).
Specimen TCGA-44-2666-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df70268e-35b9-432f-bffa-f30fc2ac687f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-2666-10A (Blood Derived Normal), aliquot TCGA-44-2666-10A-01D-A271-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2af73f9c-cbf2-4796-815a-13e66d7e41f0

The open-access MAF lists 35 somatic variants for this specimen: 31 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 29, Silent 4, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADARB1 | c.1540C>T p.R514C (on ENST00000360697 / NM_001346687.2; = p.R474C on NM_001112.4) | Missense Mutation (SNP) | VAF 9/247 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs918813031, COSV100654082; called by muse, mutect2
- CILK1 | c.1778T>A p.L593Q (on ENST00000350082 / NM_001375397.1; = p.L586Q on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.233); catalogued as COSV63154726; called by muse, mutect2, varscan2
- DDIT4 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV56577755; called by muse, mutect2, varscan2
- DDX49 | c.308T>C p.I103T | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV53231067; called by muse, mutect2, varscan2
- DYTN | c.856C>T p.L286F | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV71752367; called by muse, mutect2, varscan2
- FAT3 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53130258; called by muse, mutect2, varscan2
- HSPA9 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51864921; called by muse, mutect2
- KIF20A | c.1819T>C p.C607R | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV67510093; called by muse, mutect2
- KMT2C | c.13192G>A p.D4398N | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100075893; called by muse, mutect2
- LAIR2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs528394144, COSV56620561, COSV56621824; called by muse, mutect2, varscan2
- LRRC57 | c.143A>G p.N48S | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53000405; called by muse, mutect2
- MAP3K9 | c.1526G>T p.R509L | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV67123429; called by muse, mutect2
- MTMR10 | c.2177C>T p.T726I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV58728661; called by muse, mutect2, varscan2
- MUC16 | c.34562C>T p.A11521V | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.036); catalogued as COSV67475463; called by muse, mutect2
- NOTCH3 | c.3194A>G p.D1065G | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99658618; called by muse, mutect2
- OVCH1 | c.2871G>C p.L957F | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1263193282, COSV58964749; called by muse, mutect2
- PATZ1 | c.424T>A p.F142I | Missense Mutation (SNP) | VAF 11/320 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53229896; called by muse, mutect2
- RAB6A | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1394008095, COSV100155297; called by muse, mutect2, varscan2
- SERPINI2 | c.1043C>T p.T348I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV52986917; called by muse, mutect2, varscan2
- SETD2 | c.3964C>T p.R1322* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as COSV57441467; called by muse, mutect2, varscan2
- SHROOM1 | c.2246T>G p.L749R (on ENST00000378679 / NM_001172700.2; = p.L744R on NM_133456.2) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as COSV60581753; called by muse, mutect2, varscan2
- SLC22A6 | c.577C>A p.L193I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV64560403; called by muse, mutect2
- SYNE2 | c.8033G>T p.G2678V | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.143); catalogued as COSV59955623; called by muse, mutect2, varscan2
- TDRD10 | c.275G>C p.G92A | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV63812800; called by muse, mutect2
- TNFSF15 | c.140T>G p.L47R | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV65011893, COSV65011900; called by muse, mutect2, varscan2
- TRPM1 | c.4310C>G p.S1437C | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV56636831, COSV99855109; called by muse, mutect2, varscan2
- TTI1 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.859); catalogued as COSV100989584, COSV65062027; called by muse, mutect2, varscan2
- WDSUB1 | c.1163G>C p.R388T | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV63067519; called by muse, mutect2, varscan2
- ZNF536 | c.1699G>A p.V567M | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV62821277; called by muse, mutect2
- CD5L | c.24_28+6del p.X8_splice | Splice Site (DEL) | VAF 7/55 reads (13%) | called by mutect2, pindel, varscan2
- ARSH | c.717G>A p.E239= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV66962573; called by muse, mutect2, varscan2
- CCL2 | c.231C>T p.D77= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as rs766548953, COSV56773651; called by muse, mutect2, varscan2
- ENPP6 | c.246C>T p.R82= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV99699104; called by muse, mutect2, varscan2
- PRKG2 | c.1098G>A p.R366= | Silent (SNP) | VAF 10/219 reads (5%) | catalogued as rs1256525900, COSV52326673; called by muse, mutect2
